Somatic mutation profile of tumor specimen TCGA-63-A5M9-01A (aliquot TCGA-63-A5M9-01A-11D-A26M-08) from TCGA case TCGA-63-A5M9, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a247ca9-1618-4157-ad0b-5eeee09c5584.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5M9-10A (Blood Derived Normal), aliquot TCGA-63-A5M9-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be2ca272-ee9c-465a-b4bd-5652dde2658d

The open-access MAF lists 113 somatic variants for this specimen: 84 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 27, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 26/31 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CLDN16 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772241737, CM1312164, COSV53228138; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 20/33 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.1083G>A p.W361* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99425778; called by muse, mutect2
- ACAN | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs776772838, COSV100717375; called by muse, mutect2, varscan2
- ADGRB3 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV101000170; called by muse, mutect2, varscan2
- AHCTF1 | c.236G>A p.G79E (on ENST00000366508; = p.G53E on NM_015446.5) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100403316; called by muse, mutect2, varscan2
- AKR1D1 | c.857T>A p.I286N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99652885; called by mutect2, varscan2
- AP2A1 | c.1741G>T p.V581L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs770753280, COSV100756170, COSV62820011; called by muse, mutect2, varscan2
- AP3D1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as COSV100642461; called by muse, mutect2, varscan2
- ARL4A | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV100775892; called by muse, mutect2, varscan2
- BACH2 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as rs940966784, COSV99998277; called by muse, mutect2
- CACNA2D4 | c.2738G>T p.G913V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99765260; called by muse, mutect2, varscan2
- CBLIF | c.746C>A p.T249N | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99950791; called by muse, mutect2, varscan2
- CCT2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 106/191 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100167536; called by muse, mutect2, varscan2
- CSH1 | c.368T>A p.F123Y | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100298230; called by muse, varscan2
- CYP3A43 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99733024; called by muse, mutect2, varscan2
- DCANP1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.147); catalogued as COSV101538226; called by muse, mutect2, varscan2
- DMPK | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1380989326, COSV99352859; called by muse, mutect2, varscan2
- DSE | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.275); catalogued as COSV100528413; called by muse, mutect2, varscan2
- DYTN | c.1244T>C p.L415S | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101510812; called by muse, mutect2, varscan2
- DZIP3 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV100847687; called by muse, mutect2, varscan2
- EHBP1 | c.494+1G>A p.X165_splice | Splice Site (SNP) | VAF 108/269 reads (40%) | catalogued as rs767763438, COSV50438995; called by muse, mutect2, varscan2
- EHD2 | c.1115A>T p.H372L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV99621721; called by muse, mutect2, varscan2
- ELMO3 | c.971C>T p.A324V (on ENST00000652269; = p.A271V on NM_024712.5) | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.16); catalogued as rs906403275, COSV100681483; called by muse, mutect2, varscan2
- EMC8 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV99495658; called by muse, mutect2, varscan2
- EPHB1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); catalogued as COSV101212836; called by muse, mutect2
- FAM90A1 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); catalogued as COSV100274232; called by muse, mutect2, varscan2
- GALNT15 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100327373; called by muse, mutect2, varscan2
- GNAI3 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100879839; called by muse, mutect2, varscan2
- GPATCH8 | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101427278; called by muse, mutect2, varscan2
- IFT27 | c.500T>G p.L167R (on ENST00000433985 / NM_001363003.2; = p.L166R on NM_006860.5) | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503511; called by muse, mutect2, varscan2
- IGHV3-15 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.443); catalogued as rs1567129002; called by muse, mutect2, varscan2
- KCNQ3 | c.1955T>C p.V652A | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV101195764; called by muse, mutect2, varscan2
- KEAP1 | c.821A>G p.H274R | Missense Mutation (SNP) | VAF 81/113 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV50264820, COSV50277923; called by muse, mutect2, varscan2
- LILRB4 | c.337del p.L113Wfs*4 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | catalogued as rs1044045850; called by mutect2, pindel, varscan2
- MAB21L1 | c.671C>A p.S224* | Nonsense Mutation (SNP) | VAF 64/112 reads (57%) | catalogued as COSV100077792, COSV59795245; called by muse, mutect2, varscan2
- MAGED2 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs767820484, COSV99514433; called by muse, varscan2
- MAGEE2 | c.1122T>G p.S374R | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.862); catalogued as COSV100973017; called by muse, mutect2, varscan2
- MAGI3 | c.3073G>T p.E1025* | Nonsense Mutation (SNP) | VAF 53/79 reads (67%) | catalogued as COSV100288379; called by muse, mutect2, varscan2
- MCM8 | c.359G>C p.S120T | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV99177528; called by muse, mutect2, varscan2
- MECOM | c.2053G>A p.E685K (on ENST00000468789 / NM_001105078.4; = p.E873K on NM_004991.4) | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV99244275; called by muse, mutect2
- MFAP3L | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 73/112 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100852645; called by muse, mutect2, varscan2
- MICAL2 | c.2260T>A p.S754T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99816889; called by muse, mutect2, varscan2
- MYBPC1 | c.2052G>A p.M684I (on ENST00000550270 / NM_206820.2; = p.M709I on NM_002465.4) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100637820; called by muse, mutect2, varscan2
- NAALADL2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 94/702 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV101379977; called by muse, mutect2, varscan2
- NMD3 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768281274, COSV63618377; called by muse, mutect2, varscan2
- NUP188 | c.3027T>A p.F1009L | Missense Mutation (SNP) | VAF 131/220 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101001236; called by muse, mutect2, varscan2
- NUP62CL | c.327G>T p.L109F | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100990965; called by muse, mutect2, varscan2
- OR56A3 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 109/189 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV100290088, COSV61569830; called by muse, mutect2, varscan2
- OR8A1 | c.793A>T p.S265C | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99420403; called by muse, mutect2, varscan2
- PARS2 | c.1168A>G p.I390V | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100988288; called by muse, mutect2, varscan2
- PCDHGB3 | c.2032C>A p.R678S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV53952900, COSV99533372; called by muse, mutect2, varscan2
- PHF2 | c.681G>T p.L227F | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.559); catalogued as COSV100823065; called by muse, mutect2, varscan2
- PLA2G7 | c.921T>A p.Y307* | Nonsense Mutation (SNP) | VAF 63/142 reads (44%) | catalogued as COSV99221208; called by muse, mutect2, varscan2
- PLCB4 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 58/119 reads (49%) | catalogued as COSV99594702; called by muse, mutect2, varscan2
- POU4F2 | c.1168C>A p.R390S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55582821, COSV99850388; called by muse, mutect2, varscan2
- PRRC2A | c.5089C>G p.P1697A | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV99276612; called by muse, mutect2, varscan2
- PSG8 | c.593C>G p.T198S | Missense Mutation (SNP) | VAF 78/726 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100126049, COSV60614730; called by muse, mutect2, varscan2
- PZP | c.3446A>C p.H1149P | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV99736839; called by muse, mutect2, varscan2
- RBAK | c.142+2T>C p.X48_splice | Splice Site (SNP) | VAF 54/574 reads (9%) | catalogued as COSV100806600; called by muse, mutect2
- RYR1 | c.7813G>A p.D2605N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs754339645, COSV100614969; ClinVar: uncertain significance; called by muse, mutect2
- SALL1 | c.3929G>A p.R1310H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs372873373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SASH3 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV100795177; called by muse, mutect2, varscan2
- SLC3A1 | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 123/177 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV99576889; called by muse, mutect2, varscan2
- SPPL3 | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100793574; called by muse, mutect2, varscan2
- TG | c.5557A>G p.T1853A | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99599627; called by muse, mutect2, varscan2
- UBXN11 | c.866G>A p.R289H (on ENST00000374221 / NM_183008.2; = p.R256H on NM_145345.2) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs190924615, COSV54625248; called by muse, mutect2, varscan2
- UTRN | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs1426103781, COSV100839703, COSV62343701; called by muse, mutect2, varscan2
- VPS26B | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99844837; called by muse, mutect2, varscan2
- WDR7 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV54366984; called by muse, mutect2, varscan2
- WIPI2 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 270/395 reads (68%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99993211; called by muse, mutect2, varscan2
- XPO5 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99540571; called by muse, mutect2, varscan2
- ZBTB21 | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 134/495 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100176976; called by muse, mutect2, varscan2
- ZFP36 | c.599G>A p.R200H (on ENST00000594442; = p.R194H on NM_003407.5) | Missense Mutation (SNP) | VAF 56/434 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as rs774467387, COSV99953699; called by muse, mutect2, varscan2
- ZNF440 | c.872A>T p.K291I | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100407432; called by muse, mutect2
- ZNF521 | c.976T>C p.Y326H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100831618; called by muse, varscan2
- ZNF556 | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 96/126 reads (76%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100298614; called by muse, mutect2, varscan2
- ZNF772 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV100582777; called by muse, mutect2, varscan2
- GABRB1 | c.1125del p.N376Mfs*12 | Frame Shift Del (DEL) | VAF 83/164 reads (51%) | called by mutect2, pindel, varscan2
- IGLV3-10 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 117/240 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- KIR2DS4 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 135/343 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MCAT | c.279_288del p.A94Cfs*9 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- ZNF780B | c.2399_2404del p.Q800_K801del | In Frame Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- A2M | c.1452A>C p.G484= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100588522; called by muse, mutect2, varscan2
- ACTL6B | c.1083C>T p.L361= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV50518372; called by muse, mutect2, varscan2
- ADAT1 | c.946T>C p.L316= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as COSV100329138; called by muse, mutect2, varscan2
- ADGRF1 | c.738C>T p.D246= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs751673726, COSV51948420, COSV99347042; called by muse, mutect2, varscan2
- ARHGAP36 | c.231C>T p.L77= | Silent (SNP) | VAF 106/301 reads (35%) | catalogued as COSV52270636, COSV99357387; called by muse, mutect2, varscan2
- CDC42BPB | c.627C>T p.D209= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs761287992, COSV63473948; called by muse, mutect2, varscan2
- CYP2S1 | c.948G>T p.L316= | Silent (SNP) | VAF 32/366 reads (9%) | catalogued as COSV100027373; called by muse, mutect2
- DNAH9 | c.3223C>T p.L1075= | Silent (SNP) | VAF 58/291 reads (20%) | catalogued as COSV99304783; called by muse, mutect2, varscan2
- FAM83H | c.282A>T p.T94= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV101186934; called by muse, mutect2, varscan2
- MRO | c.177C>T p.D59= | Silent (SNP) | VAF 38/204 reads (19%) | catalogued as COSV56497020, COSV99839057; called by muse, mutect2, varscan2
- MTMR11 | c.1950C>T p.L650= (on ENST00000439741 / NM_001145862.2; = p.L578= on NM_181873.3) | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99640998; called by muse, mutect2, varscan2
- MYH10 | c.4014C>T p.I1338= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99344483; called by muse, mutect2, varscan2
- MYLPF | c.51C>T p.S17= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs140103472; called by muse, mutect2, varscan2
- NMRK2 | c.657G>T p.T219= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs146363585, COSV99396268; called by muse, mutect2, varscan2
- NT5C1B | c.1257G>A p.L419= (on ENST00000359846 / NM_001199086.2; = p.L359= on NM_033253.4) | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as COSV100409890, COSV58399253; called by muse, mutect2, varscan2
- PCDHB8 | c.1956G>A p.P652= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs782285661, COSV50767905; called by muse, mutect2
- PDZD4 | c.786G>A p.G262= | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as rs782412283, COSV99381134; called by muse, mutect2, varscan2
- PKHD1 | c.12201G>A p.P4067= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as rs750988521, COSV64390169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRH | c.814T>C p.L272= | Silent (SNP) | VAF 108/246 reads (44%) | catalogued as COSV99670813; called by muse, mutect2, varscan2
- RNF215 | c.855C>T p.L285= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs764844213, COSV99306432; called by muse, mutect2, varscan2
- RYR3 | c.13518G>A p.R4506= (on ENST00000389232; = p.R4507= on NM_001036.6) | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs1362198099, COSV101212189; called by muse, mutect2, varscan2
- SLC25A2 | c.333C>T p.A111= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs782238065, COSV99508175; called by muse, mutect2, varscan2
- SPAG4 | c.531T>C p.F177= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as COSV100958276; called by muse, mutect2, varscan2
- TBC1D23 | c.45C>A p.G15= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV100792491; called by muse, mutect2, varscan2
- XPNPEP2 | c.363T>A p.A121= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV100941175; called by muse, mutect2, varscan2
- ZFHX3 | c.6699T>G p.P2233= | Silent (SNP) | VAF 83/289 reads (29%) | catalogued as COSV99195754; called by muse, mutect2, varscan2
- ZIC1 | c.249G>T p.P83= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99291645; called by muse, mutect2, varscan2
- EIF4G2 | c.1413+179T>C | Intron (SNP) | VAF 82/136 reads (60%) | catalogued as COSV100379424; called by muse, mutect2, varscan2
- MAP4K4 | c.1867-936G>A | Intron (SNP) | VAF 48/168 reads (29%) | catalogued as rs763083141, COSV100615510; called by muse, mutect2
